Gene-level copy-number profile of tumor specimen TCGA-G2-A2EF-01A from TCGA case TCGA-G2-A2EF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 50.6 years (18,467 days).
Specimen TCGA-G2-A2EF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.a18e299e-1e10-46a4-a8bf-ab381194e0a5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-A2EF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e5ac2b49-0043-4c43-a031-e1f53ecc6045

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,105; copy number 2: 18,536; copy number 3: 25,144; copy number 4: 7,649; copy number 5: 1,571; copy number 6: 4,504; copy number 7: 1,077; copy number 8: 18; copy number 9: 45; copy number 10: 16; copy number 11: 55; copy number 12: 31; copy number 13: 3; copy number 14: 14; copy number 15: 27; copy number 20: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-A2EF-01A-12D-A18E-01): tumor purity 0.61, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene: RPS16P3.
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr16:71,281,389–71,289,715, 1 gene: CMTR2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,289 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:78,088,729–87,196,629, 141 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:80,163,327–81,105,182, 7 genes, copy number 9 (within-gene range 5–9): OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027.
- chr3:171,058,414–171,996,871, 12 genes, copy number 7: TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1.
- chr5:58,198–40,755,963, 627 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr6:17,530,899–21,232,404, 48 genes, copy number 7–11 (within-gene range 5–11): RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P.
- chr9:13,927,971–21,351,378, 115 genes, copy number 11–20 (broad region; genes not listed).
- chr9:30,388,935–30,990,572, 9 genes, copy number 10: LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17.
- chr13:54,938,604–56,885,602, 9 genes, copy number 7: AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, AL138997.1, SPATA2P1, RN7SKP6.
- chr17:37,609,739–38,257,192, 21 genes, copy number 9: AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA.
- chr19:7,069,703–7,497,449, 7 genes, copy number 10 (within-gene range 6–10): ZNF557, INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G.
- chr22:21,103,016–25,207,359, 293 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,081. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
